Somatic mutation profile of tumor specimen C3L-00771-01 (aliquot CPT0026770009) from CPTAC case C3L-00771, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 86.7 years (31,649 days).
Specimen C3L-00771-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17b43359-8401-41fc-9a4c-c73b5f086c0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00771-71 (Blood Derived Normal), aliquot CPT0026830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c349319-634f-4e1e-842b-8367b251590f

The open-access MAF lists 110 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 26, Nonsense Mutation 6, 3'UTR 4, Frame Shift Del 4, RNA 3, Frame Shift Ins 3, 5'Flank 2, Intron 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.3646G>A p.V1216M | Missense Mutation (SNP) | VAF 72/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776280797, CM980192; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 50/336 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>T p.M1043L | Missense Mutation (SNP) | VAF 39/189 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 130/504 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 46/309 reads (15%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS15 | c.2727C>A p.C909* | Nonsense Mutation (SNP) | VAF 29/175 reads (17%) | catalogued as COSV54510164; called by muse, mutect2, varscan2
- ADRA1B | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1326041512; called by muse, mutect2, varscan2
- ATP8B2 | c.2036C>T p.T679M (on ENST00000672630; = p.T646M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs776972025, COSV59246518; called by muse, mutect2, varscan2
- C7 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as rs369760989, COSV57479843; called by muse, mutect2, varscan2
- CACNA1I | c.5120C>T p.P1707L | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320935267; called by muse, mutect2, varscan2
- CHD4 | c.3356G>C p.G1119A (on ENST00000357008 / NM_001363606.2; = p.G1132A on NM_001273.5) | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58910327; called by muse, mutect2
- CPAMD8 | c.2146C>T p.R716C (on ENST00000651564; = p.R669C on NM_015692.5) | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs778538042; called by muse, mutect2, varscan2
- DRP2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs201156733, COSV65811862; called by muse, mutect2, varscan2
- GPC5 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65575216; called by muse, mutect2, varscan2
- H3-5 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 64/353 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.195); catalogued as rs141415515, COSV61186887; called by muse, mutect2, varscan2
- KCND2 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58576011; called by muse, mutect2, varscan2
- KLHL1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1443717861, COSV64778491; called by muse, mutect2, varscan2
- KMT2B | c.4736G>A p.R1579H | Missense Mutation (SNP) | VAF 53/308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55865736; called by muse, mutect2, varscan2
- LIM2 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 68/428 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV55741741; called by muse, mutect2, varscan2
- LRMDA | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 35/268 reads (13%) | catalogued as rs200848450; called by muse, mutect2, varscan2
- MBD1 | c.1378C>T p.R460W (on ENST00000269468 / NM_001323950.1; = p.R404W on NM_002384.2) | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1164534782; called by muse, mutect2
- NRG3 | c.2035G>A p.V679I (on ENST00000404547 / NM_001370084.1; = p.V655I on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.09); catalogued as rs143042604; called by muse, mutect2, varscan2
- NTRK1 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as rs986498490, COSV100693668; called by muse, mutect2, varscan2
- OR2T8 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 45/442 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as rs1209573680, COSV60664076; called by muse, varscan2
- PCDHA6 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV65352427; called by muse, mutect2, varscan2
- PCDHGA3 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs770576379, COSV99533745, COSV99540825; called by muse, mutect2, varscan2
- PCDHGB3 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV54056567; called by muse, mutect2, varscan2
- PIK3CA | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55932192, COSV55944790; called by muse, mutect2
- PLCL1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334903017, COSV70838744; called by muse, mutect2, varscan2
- PSCA | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs782076248, COSV100008228, COSV56653048; called by muse, mutect2
- PTPN3 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 21/182 reads (12%) | catalogued as rs761449301, COSV52708323; called by muse, mutect2, varscan2
- RANBP3 | c.1473G>A p.S491= (on ENST00000340578 / NM_007322.3; = p.S486= on NM_003624.3) | Splice Region (SNP) | VAF 21/84 reads (25%) | catalogued as rs1012413726, COSV50382238; called by muse, mutect2
- RBM27 | c.2854C>T p.R952* | Nonsense Mutation (SNP) | VAF 21/118 reads (18%) | catalogued as COSV54594783; called by muse, mutect2, varscan2
- RPH3A | c.1349C>G p.T450S (on ENST00000389385 / NM_001143854.2; = p.T446S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs869312710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RRAS2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329970, COSV56331263; called by muse, mutect2, varscan2
- S1PR1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59514372; called by muse, mutect2, varscan2
- SAMD4A | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs781289174, COSV51887034; called by muse, mutect2, varscan2
- SIGLEC1 | c.3769C>T p.R1257W | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs138190270; called by muse, mutect2, varscan2
- SLC43A2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.094); catalogued as rs748564128, COSV56771880; called by muse, mutect2, varscan2
- SLC9A6 | c.1632-5C>T | Splice Region (SNP) | VAF 32/288 reads (11%) | catalogued as rs1556622334; called by muse, mutect2, varscan2
- STARD8 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs759164995, COSV99367109; called by muse, mutect2
- TLR8 | c.322G>A p.G108S (on ENST00000218032 / NM_138636.5; = p.G126S on NM_016610.4) | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1281012171, COSV54317935; called by muse, mutect2, varscan2
- TRAV9-2 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs186180839; called by muse, mutect2, varscan2
- UPF3B | c.1103G>A p.R368Q (on ENST00000276201 / NM_080632.3; = p.R355Q on NM_023010.3) | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.551); catalogued as rs1282813621, CM107802, COSV52231276; called by muse, varscan2
- ZMIZ2 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1263359200; called by muse, mutect2, varscan2
- ZNF713 | c.527_528del p.C176* (on ENST00000633730 / NM_001366796.2; = p.C189* on NM_182633.3) | Frame Shift Del (DEL) | VAF 27/180 reads (15%) | catalogued as rs757880273; called by mutect2, pindel, varscan2
- ZXDA | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62389104; called by muse, mutect2, varscan2
- ZXDC | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 26/216 reads (12%) | catalogued as rs763498935; called by muse, mutect2
- ADGRE2 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- BRD2 | c.932C>G p.A311G | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C5orf38 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CCDC160 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DENND11 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ERCC4 | c.984dup p.L329Sfs*2 | Frame Shift Ins (INS) | VAF 34/268 reads (13%) | called by mutect2, pindel, varscan2
- EVX2 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMR1 | c.1236T>A p.N412K | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.97A>G p.T33A (on ENST00000354667 / NM_031243.3; = p.T21A on NM_002137.4) | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- HTR6 | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNH8 | c.1058del p.T353Ifs*4 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- KCNQ1 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KRTAP2-4 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- LAMB4 | c.1132_1145del p.F378Afs*14 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- MCF2 | c.1930-1G>A p.X644_splice | Splice Site (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- NBPF12 | c.2496G>T p.W832C | Missense Mutation (SNP) | VAF 64/449 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDH8 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- PCLO | c.14464_14470del p.W4822Lfs*93 | Frame Shift Del (DEL) | VAF 16/139 reads (12%) | called by mutect2, pindel
- PTPRQ | c.267G>T p.W89C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.535); called by muse, mutect2
- RBP3 | c.2638G>T p.G880C | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RESF1 | c.1114dup p.I372Nfs*27 | Frame Shift Ins (INS) | VAF 14/119 reads (12%) | called by mutect2, pindel, varscan2
- RPGRIP1L | c.1549A>C p.I517L | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 86/562 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, varscan2
- ZFHX3 | c.9019dup p.S3007Kfs*14 | Frame Shift Ins (INS) | VAF 54/297 reads (18%) | called by mutect2, pindel, varscan2
- ZNF408 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA4 | c.4362C>T p.P1454= | Silent (SNP) | VAF 46/323 reads (14%) | called by muse, mutect2, varscan2
- ADCY1 | c.379C>T p.L127= | Silent (SNP) | VAF 56/304 reads (18%) | called by muse, mutect2, varscan2
- ADGRB3 | c.267G>A p.Q89= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as rs1024078581; called by muse, mutect2, varscan2
- BAHCC1 | c.1134G>A p.P378= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1555652845; called by muse, mutect2, varscan2
- CDH23 | c.4782C>T p.R1594= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs756336099, COSV56457855; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- CLRN3 | c.540G>A p.S180= | Silent (SNP) | VAF 57/427 reads (13%) | catalogued as rs1326547005, COSV64098812; called by muse, mutect2, varscan2
- CLTB | c.675G>A p.T225= (on ENST00000310418 / NM_007097.5; = p.T207= on NM_001834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs761220106, COSV51257744; called by muse, mutect2
- CNMD | c.51C>T p.D17= | Silent (SNP) | VAF 25/191 reads (13%) | catalogued as COSV65033036; called by muse, mutect2, varscan2
- CNTNAP5 | c.1209G>T p.L403= | Silent (SNP) | VAF 52/281 reads (19%) | catalogued as rs779415606; called by muse, mutect2, varscan2
- DGLUCY | c.978G>A p.S326= | Silent (SNP) | VAF 69/287 reads (24%) | catalogued as rs767862215, COSV56369934; called by muse, mutect2, varscan2
- DTX4 | c.309G>A p.T103= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs558443267; called by muse, mutect2, varscan2
- FIBCD1 | c.1002C>T p.D334= | Silent (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- JPH1 | c.969C>T p.D323= | Silent (SNP) | VAF 62/441 reads (14%) | called by muse, mutect2, varscan2
- KLB | c.2208G>A p.G736= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1581C>T p.P527= (on ENST00000395676; = p.P1168= on NM_138433.5) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs567913682; called by muse, mutect2
- KLHL34 | c.1458C>T p.G486= | Silent (SNP) | VAF 36/178 reads (20%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2076G>A p.A692= | Silent (SNP) | VAF 55/306 reads (18%) | catalogued as COSV65376869; called by muse, mutect2, varscan2
- PHACTR1 | c.210G>A p.P70= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2
- RRAGD | c.522C>T p.F174= | Silent (SNP) | VAF 37/255 reads (15%) | catalogued as rs1470235600, COSV100784613, COSV63268951; called by muse, mutect2, varscan2
- SC5D | c.795G>A p.P265= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs1031818443, COSV50612611; called by muse, mutect2, varscan2
- SERINC3 | c.492C>T p.G164= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- SETMAR | c.1875C>T p.H625= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as rs766759932; called by muse, mutect2, varscan2
- SLC49A4 | c.918T>A p.I306= | Silent (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- SPSB3 | c.486C>T p.T162= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs376234209; called by muse, mutect2, varscan2
- TRIM55 | c.717G>A p.E239= | Silent (SNP) | VAF 49/327 reads (15%) | catalogued as rs147151340; called by muse, mutect2, varscan2
- WDFY4 | c.3912A>G p.R1304= | Silent (SNP) | VAF 62/186 reads (33%) | called by muse, mutect2, varscan2
- AKR1E2 | chr10:4825030 C>T | 5'Flank (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- H3-2 | c.*206G>A | 3'UTR (SNP) | VAF 56/373 reads (15%) | catalogued as rs782614090; called by muse, mutect2, varscan2
- HSP90AB3P | n.2064G>A | RNA (SNP) | VAF 47/258 reads (18%) | called by muse, mutect2, varscan2
- IL13RA1 | c.1009+3356C>A | Intron (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- KHNYN | c.*4535A>G | 3'UTR (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- MALRD1 | c.4688-265C>A | Intron (SNP) | VAF 11/49 reads (22%) | called by muse, varscan2
- RAB7A | c.*51T>G | 3'UTR (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1099G>A | RNA (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- SVIL2P | n.2103C>T | RNA (SNP) | VAF 29/236 reads (12%) | catalogued as rs748409592; called by muse, mutect2, varscan2
- UBAP2L | c.*62G>A | 3'UTR (SNP) | VAF 19/126 reads (15%) | catalogued as rs1157813787; called by muse, mutect2, varscan2
- WT1 | chr11:32439150 C>T | 5'Flank (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
